Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8429, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8429-01A (Primary Tumor).

[page 1 of 3]
A. KIDNEY, RIGHT NEPHRECTOMY:

RENAL CELL CARCINOMA, chromophobe type (1.8 cm), Fuhrman nuclear grade II-III of IV, extensively involving the renal parenchyma (See NOTE).

Tumor invades into perinephric adipose tissue.

Renal vein, ureter and perinephric fat resection margins are negative for tumor.

No definitive lymphovascular invasion identified.

Adrenal gland is not present.

Tumor cells are positive for Hale's colloidal iron and CD10 (multifocally). The tumor is negative for RCC and WT-1 immunostains.

The non-neoplastic kidney is evaluated by Renal Pathology Service, and the findings are reported below.

AJCC Classification (6th edition): [REDACTED]

NOTE

The tumor has typical chromophobe carcinoma cytology (well-defined cell borders, perinuclear halos, binucleation) as well as focal pseudo-papillary architecture, cystic degeneration and numerous psammomatous calcifications. Cell cultures were attempted but unsuccessful, and the cytogenetic analysis could not be performed. [REDACTED] Given the unusual morphology and relatively young age of the patient, FISH for Xp translocation was attempted, but was also unsuccessful.

B. REGIONAL RIGHT RETROPERITONEAL LYMPH NODES:

Fibrous adipose tissue with no tumor present.

No lymphoid tissue present.

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

RIGHT KIDNEY, NEPHRECTOMY:

MINIMAL CHRONIC CHANGES OF THE KIDNEY PARENCHYMA WITH MILD ARTERIOLAR HYALINOSIS (SEE NOTE).

NOTE

Very mild chronic changes are present, including global glomerulosclerosis affecting less than 1% of glomeruli, tubular atrophy and interstitial fibrosis affecting less than 5% of the cortical parenchyma, and mild arteriolar hyaline. There are no glomerular changes suggestive of early diabetic sclerosis (family history of diabetes).

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A9) were evaluated using H&E, PAS, Jones silver methenamine, and AFO3 (trichrome) stains.

[page 2 of 3]
The sample consists of cortex and medulla. There are 219 glomeruli present, of which 2 (0.9%) are globally sclerosed. The remaining glomeruli show no significant expansion of the mesangial areas. There are no discernible craters or double contours of the glomerular capillary wall basement membranes. Rare distal tubules contain PAS-positive hyaline casts and a few display focal prominences of reabsorption granules. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arterioles exhibit mild hyalineosis.

CLINICAL DATA:

Clinical History: A 35-year-old female with 13 cm right renal mass.
Operation: Right radical nephrectomy, regional lymphadenectomy.
Operative Findings: None given.
Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1. Right kidney
B/2. Regional right retroperitoneal nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in three parts, each labeled with the patient's name unit number.

Part A, "right kidney", consists of a 2032 gram right radical nephrectomy specimen (26.0 x 18.0 x 12.0) including kidney, surrounding perirenal fat, and a portion of Gerota's fascia (up to 9.0 cm). Extending from the renal pelvis is the ureter (4.0 cm in length x 0.5 cm in diameter), renal vein (1.0 cm in length x 2.0 cm in diameter), and renal artery (5.0 cm in length x 0.4 cm in diameter). A very large encapsulated mass is identified (18.0 x 12.0 x 12.0 cm) and replaces most of the renal parenchyma. It has a tan/yellow and mostly solid heterogeneous cut surface, with large areas of hemorrhage and focal cystic degeneration. It abuts the renal pelvis and occupies a large portion of the perinephric fat. It extends to within 3.0 cm of the renal vein margin, 7.0 cm of the ureter margin, and 6.0 cm of the renal artery margin. A small portion of residual renal parenchyma is present in the upper pole; the residual pelvocaliceal system and adjacent parenchyma are markedly distorted by the tumor. The renal cortex is tan/brown with a well-defined cortico-medullary junction. The adrenal gland is not identified. The adipose tissue is thinly sectioned and no lymph nodes are identified. Representative sections of the tumor mass are submitted for tissue banking and cytogenetics. Representative sections of the normal kidney are submitted for electron microscopy and immunofluorescence studies (on hold). Gross photographs are taken.

Micro A1: Renal vein, renal artery and ureter margins, 3 frags,

Micro A3-A6: Tumor to capsule and perirenal fat, 5 frags,

Micro A7 and A8: Tumor and adjacent normal kidney, 2 frags

Micro A9: Uninvolved kidney, 1 frag, RSS.

Micro A10-A15: additional tumor to include renal pelvis, multiple frags.

Part B, "regional right retroperitoneal nodes", consists of a fragment of fibroadipose tissue (6.5 x 4.3 x 0.5 cm), which is thinly sectioned and no palpable lymph nodes are identified. The specimen is entirely submitted.

Micro B1-B5: tissue, multiple frags.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[page 3 of 3]
Accession Number: [REDACTED] Report Status: Preliminary
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

PATHOLOGIC DIAGNOSIS:

HEAL FOR: Immunohistochemistry and cytogenetics
PRELIMINARY DIAGNOSIS: Renal cell carcinoma (held for cytogenetics and immunohistochemical stains)

Pathologist: [REDACTED]

CLINICAL DATA:

History: [REDACTED] Workup for sciatica found
large R renal mass.
Operation: Hand-assisted laparoscopic nephrectomy.
Operative Findings: Large right renal mass.
Clinical Diagnosis: Renal cell CA mass.

TISSUE SUBMITTED:

#1 Right kidney [REDACTED]

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number, and "1. Right kidney", and consists of 573 gm right nephrectomy specimen (16 x 11 x 8 cm), including a kidney (15 x 7.5 x 6.3 cm) with attached perirenal adipose (up to 6.0 cm). A 2.2 cm renal artery (diameter 0.5 cm), a 1.3 cm renal vein (diameter 0.9 cm), and a 8.5 cm ureter (0.5 cm) are present at the hilum and are grossly unremarkable. Gerota's fascia has been previously partially inked black. The specimen contains a well-circumscribed, tan/yellow, hemorrhagic mass, which expands to but does not grossly invade the renal capsule at the lower pole, 2.5 cm from the hilar vessels. The perirenal fat over the tumor is freely mobile, without gross evidence of involvement. Representative tumor was taken for EM, cytogenetics, and tumor bank, and representative normal kidney was sent for EM, IF, and tumor bank. There is no adrenal gland present, and the remaining renal tissue is grossly unremarkable without additional lesions or other abnormalities. The renal pelvis is likewise grossly unremarkable, lined by light tan, trabecular mucosa without abnormality.

Micr > A1: Vascular, ureteral margins, 1 frag, [REDACTED]
Micr > A2: Mass and closest, inked, adipose tissue margin, 1 frag, [REDACTED]
Micr > A3: Mass, 1 frag, [REDACTED]
Micr > A4: Mass and adjacent, uninvolved kidney, 2 frags, [REDACTED]
Micr > A5: Mass and adjacent renal vein, 1 frag, [REDACTED]
Micr > A6: Uninvolved kidney, 1 frag, [REDACTED]

By E.S./her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file fcf56081-bf99-43a0-a982-7b8bb46daab9 (TCGA-KN-8429.44B1F6E7-9FAB-4055-946A-E05C02873261.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).